Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A8LL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A8LL-06A (Metastatic).

[page 1 of 2]
ICD-3
Melanoma NOS 8720/3
Site Pelvic lymph nodes
077.5
Q211/2 4/13

SPECIMENS:

- A. SUPERFICIAL LEFT GROIN LYMPH NODE
- B. HERNIA SAC
- C. MOST PROXIMAL LEFT EXTERNAL ILIAC LYMPH NODE
- D. LEFT EXTERNAL ILIAC LYMPH NODES
- E. LEFT OBTURATOR LYMPH NODES

SPECIMEN(S):

- A. SUPERFICIAL LEFT GROIN LYMPH NODE
- B. HERNIA SAC
- C. MOST PROXIMAL LEFT EXTERNAL ILIAC LYMPH NODE
- D. LEFT EXTERNAL ILIAC LYMPH NODES
- E. LEFT OBTURATOR LYMPH NODES

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

TPC-most proximal left external iliac lymph node: Negative for metastasis (0/1).
Diagnosis called by Dr. to Dr. at

DIAGNOSIS:

- A. LYMPH NODE, SUPERFICIAL LEFT GROIN, EXCISION:
- FOUR OUT OF EIGHT LYMPH NODES, POSITIVE FOR METASTASIS, CONSISTENT WITH METASTATIC MELANOMA (4/8)
- FRAGMENT OF SKIN AND SUBCUTANEOUS TISSUE, NEGATIVE FOR MALIGNANCY
- B. HERNIA SAC, EXCISION:
- CONSISTENT WITH HERNIA SAC
- NEGATIVE FOR MALIGNANCY
- C. LYMPH NODE, LEFT EXTERNAL ILIAC, MOST PROXIMAL, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- D. LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION:
- ONE OUT OF THREE LYMPH NODES, POSITIVE FOR METASTASIS, CONSISTENT WITH METASTATIC MELANOMA (1/3)
- E. LYMPH NODES, LEFT OBTURATOR, EXCISION:
- THREE LYMPH NODES, NEGATIVE FOR METASTATIC MELANOMA (0/3)

GROSS DESCRIPTION:

A. SUPERFICIAL LEFT GROIN LYMPH NODE

Received fresh labeled with the patient's identification and 'superficial left groin lymph node' is a tan yellow fragment of lobulated adipose tissue 39 x 13 x 7cm. The specimen is partially surfaced with a tan pink ellipse of skin 7 x 2cm. The skin surface is remarkable for a tan grey well healed scar 3.2cm. Dissection reveals eight lymph nodes ranging from 5.5 x 4 x 3cm to 0.7 x 0.6 x 0.5cm. The two largest lymph nodes are serially sectioned to reveal a pigmented homogenous cut surface. A portion of the largest lymph node is submitted for tissue procurement.

A1: skin

A2: three lymph nodes

A3: two lymph nodes

A4: one lymph node

A5-A6: one lymph node

A7-A10: representative sections of largest lymph node

B. HERNIA SAC

Received in formalin labeled with the patient's identification and "hernia sac" is a piece of fibro-encapsulated fat, 7.5 x 4.8 x 1.7 cm. Sectioned, it has a uniform yellow-tan cut surface. No discrete lesions are identified; representatively submitted, B1-B2.

C. MOST PROXIMAL LEFT EXTERNAL ILIAC LYMPH NODE

[page 2 of 2]
Received fresh labeled with the patient's identification and "most proximal external iliac lymph node" is a 1.5 x 0.7 x 0.7 cm lymph node. It is sectioned and a touch prep is performed; lymph node is submitted entirely, C1.

D. LEFT EXTERNAL ILIAC LYMPH NODES

Received in formalin labeled with patient's identification and "left external iliac lymph node" is a piece of yellow-tan soft tissue, 7.4 x 5.3 x 1.4 cm containing 3 lymph nodes, 2.7 x 1.5 x 0.8 cm, 3.1 x 20.9 cm, and 3.4 x 2.2 x 1.3 cm. The lymph nodes are sectioned and have pink-tan cut surfaces; lymph node is submitted entirely:

D1:1 bisected lymph node

D2-D3: 1 bisected lymph node

D4-D6: 1 sectioned lymph node

E. LEFT OBTURATOR LYMPH NODES

Received in formalin labeled with the patient's identification and "left obturator lymph node" is a piece of yellow-tan soft tissue, 5.1 x 2.4 x 1.3 cm containing 3 lymph nodes, 0.4 x 0.4 x 0.2 cm, 0.7 x 0.5 x 0.4 cm, and 5.3 x 1.7 x 1.1 cm. The largest lymph node is sectioned and has a yellow-tan cut surface; lymph nodes are submitted entirely:

E1: 2 lymph nodes

E2-E6: 1 sectioned lymph node

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Left groin nodal metastatic melanoma

Gross Dictation:

Microscopic/Diagnostic Dictation:., Pathologist.

Microscopic/Diagnostic Dictation:., ,

Final Review:., Pathologist,

Final:., Pathologist

ILPAA Discrepancy		/

Source: NCI Genomic Data Commons file 13ea067f-fea0-4adc-89b2-bcf046523e8a (TCGA-GN-A8LL.B7B7B00E-578B-49B5-9250-A75C6A1C2933.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).